Somatic mutation profile of tumor specimen ALCH-B1RC-TTP1-A (aliquot ALCH-B1RC-TTP1-A-20-0-D-A710-36) from ALCHEMIST case ALCH-B1RC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 46.6 years (17,006 days).
Specimen ALCH-B1RC-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5848ecbb-4089-423b-9ab8-b5b0bc4e2a3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1RC-NB1-A (Blood Derived Normal), aliquot ALCH-B1RC-NB1-A-1-0-D-A710-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7d3e794-ebf4-4c3c-8dc3-b01e0b9a32bb

The open-access MAF lists 27 somatic variants for this specimen: 24 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Nonsense Mutation 2, Silent 2, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ELMO1 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs778770532, COSV60302130, COSV60317391; called by muse, mutect2
- NUP214 | c.4054G>A p.A1352T | Missense Mutation (SNP) | VAF 40/347 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs142720685; called by muse, mutect2, varscan2
- OLFML1 | c.705G>T p.E235D | Missense Mutation (SNP) | VAF 42/446 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV55081661; called by muse, mutect2
- PCDHGA3 | c.2227G>A p.A743T | Missense Mutation (SNP) | VAF 33/426 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV53951173; called by muse, mutect2
- PCNX4 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 33/270 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); catalogued as rs762027944, COSV58307722, COSV58309210; called by muse, mutect2, varscan2
- POGLUT3 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372841756; called by muse, mutect2, varscan2
- PRR14L | c.1580T>C p.V527A | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV57885593; called by muse, mutect2
- SMG8 | c.2948G>T p.R983L | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.552); catalogued as rs778535729, COSV56286797; called by muse, mutect2, varscan2
- AICDA | c.67G>C p.G23R | Missense Mutation (SNP) | VAF 30/291 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTN1A1 | c.885G>A p.W295* | Nonsense Mutation (SNP) | VAF 17/133 reads (13%) | called by muse, mutect2, varscan2
- CCDC146 | c.1968A>C p.E656D | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- CEP162 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- GPAM | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 48/403 reads (12%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SF3B3 | c.2236G>A p.A746T | Missense Mutation (SNP) | VAF 14/352 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2
- SLC5A4 | c.1148T>G p.L383R | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SLIT3 | c.2960G>T p.G987V | Missense Mutation (SNP) | VAF 37/307 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLITRK5 | c.891G>T p.Q297H | Missense Mutation (SNP) | VAF 37/237 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- SNW1 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 19/377 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.077); called by muse, mutect2
- TXNL1 | c.446G>T p.C149F | Missense Mutation (SNP) | VAF 20/297 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.21); called by muse, mutect2
- UBN1 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 28/604 reads (5%) | called by muse, mutect2
- VPS13D | c.10192A>G p.I3398V | Missense Mutation (SNP) | VAF 31/271 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WSCD1 | c.1119T>A p.H373Q | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- ZNF654 | c.2565del p.F855Lfs*16 | Frame Shift Del (DEL) | VAF 27/187 reads (14%) | called by mutect2, pindel, varscan2
- ZSWIM8 | c.1255A>G p.M419V | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); called by muse, mutect2
- ACSL5 | c.1959G>A p.G653= (on ENST00000354273; = p.G709= on NM_016234.3) | Silent (SNP) | VAF 16/182 reads (9%) | called by muse, mutect2
- ERBB2 | c.399C>A p.S133= | Silent (SNP) | VAF 23/180 reads (13%) | called by muse, mutect2, varscan2
- OR1F2P | n.370G>A | RNA (SNP) | VAF 28/296 reads (9%) | catalogued as rs770806410; called by muse, mutect2
